Somatic mutation profile of tumor specimen BA2850D (aliquot aq-BA2850D) from BEATAML1.0 case 2210, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 50.5 years (18,430 days).
Specimen BA2850D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 466f9691-ba08-4b13-be07-1362fe95182c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2274D (Solid Tissue Normal), aliquot aq-BA2274D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5376c5b8-8336-4649-b1f0-6f00b159867a

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, 3'Flank 2, In Frame Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 24/45 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs147001633, COSV53036153, COSV53040144, COSV53040431; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A4GALT | c.1034C>T p.T345M | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs754861621, COSV50746909; called by muse, mutect2, varscan2
- CELSR2 | c.58_60dup p.L25dup | In Frame Ins (INS) | VAF 4/28 reads (14%) | catalogued as rs72555380, COSV54776188; called by mutect2, varscan2
- ROBO1 | c.4156G>A p.G1386R | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT tolerated (0.79); PolyPhen benign (0.009); catalogued as COSV71393667; called by muse, mutect2, varscan2
- SMR3B | c.85C>G p.P29A | Missense Mutation (SNP) | VAF 55/98 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as COSV59229436; called by muse, mutect2, varscan2
- ZFHX4 | c.2547C>A p.F849L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1250836707, COSV99268292; called by muse, mutect2, varscan2
- DVL3 | c.1707C>A p.H569Q | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.425); called by muse, mutect2
- FCHO1 | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TTC17 | c.1808T>C p.I603T | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- JAKMIP3 | c.1296G>A p.K432= | Silent (SNP) | VAF 17/192 reads (9%) | catalogued as rs1448956470; called by muse, mutect2
- MYL3 | chr3:46833609 C>T | 3'Flank (SNP) | VAF 69/147 reads (47%) | called by muse, mutect2, varscan2
- NDUFB10 | chr16:1965236 G>T | 3'Flank (SNP) | VAF 7/94 reads (7%) | called by muse, mutect2
